TCGA case TCGA-27-1831 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f45f4a30-6b4c-4f15-9140-959d6a25a45f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 505 days (1.4 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 66.9 years (24,447 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: -8 days; Days to treatment end: 505 days (1.4 years); Treatment dose: 4,104 mg; Prescribed dose: 8; Prescribed dose units: mg.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Oxcarbazepine; Treatment intent type: Adjuvant; Days to treatment start: -8 days; Days to treatment end: 505 days (1.4 years); Treatment dose: 307,800 mg; Prescribed dose: 600; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 4 days; Days to treatment end: 98 days; Number of cycles: 3; Treatment dose: 420 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 103 days; Number of cycles: 3; Treatment dose: 3,400 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 39 days; Days to treatment end: 84 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 67.3 years (24,591 days); Days to diagnosis: 144 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 144 (post initial treatment): Progression or recurrence: Yes; Days to progression: 144 days.
- Days to follow up: 505 days (1.4 years); Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-27-1831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.5; Shortest dimension: 1.
  Slide TCGA-27-1831-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-27-1831-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
- Sample TCGA-27-1831-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-27-1831-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 505 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 505 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 144 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-27-1831-01A-01D-0784-01): tumor purity 0.7, ploidy 2.07, whole-genome doublings 0.
